Somatic mutation profile of tumor specimen TCGA-XF-AAN5-01A (aliquot TCGA-XF-AAN5-01A-11D-A42E-08) from TCGA case TCGA-XF-AAN5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 61.4 years (22,411 days).
Specimen TCGA-XF-AAN5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e949980c-b70b-47c5-a4b0-80403841a8b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAN5-10A (Blood Derived Normal), aliquot TCGA-XF-AAN5-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd6ccd74-1b1c-4310-a059-4143677e0762

The open-access MAF lists 342 somatic variants for this specimen: 260 protein-altering or splice-affecting, 70 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 70, Nonsense Mutation 29, Frame Shift Del 5, Splice Site 4, Frame Shift Ins 3, 5'Flank 3, RNA 3, Intron 2, 3'UTR 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 35/145 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs1567847905, CM1110584, COSV62191872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.89_100del p.L30_S33del | In Frame Del (DEL) | VAF 11/44 reads (25%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA5 | c.1821C>G p.I607M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101201056; called by muse, mutect2, varscan2
- ABCA9 | c.4330C>G p.L1444V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100382838; called by muse, mutect2, varscan2
- ABCB4 | c.2354G>A p.R785K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55932345; called by muse, mutect2, varscan2
- ACE | c.3131G>A p.S1044N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52013307, COSV99326670; called by muse, mutect2
- ACO2 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99347195; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4007G>C p.R1336T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54461766, COSV99716284; called by muse, mutect2, varscan2
- ADGRG3 | c.1035C>A p.F345L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV100342197; called by muse, mutect2, varscan2
- ADGRG4 | c.8874del p.F2958Lfs*6 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | catalogued as rs771931957; called by mutect2, pindel, varscan2
- ADGRL2 | c.3018T>G p.I1006M (on ENST00000370717 / NM_001366005.1; = p.I993M on NM_012302.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99587821; called by muse, mutect2, varscan2
- ADH4 | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as rs1197166809, COSV99644077; called by muse, mutect2, varscan2
- AJUBA | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52985567, COSV52986160; called by muse, mutect2, varscan2
- ARHGAP31 | c.2411C>A p.P804Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs760373610, COSV51798106, COSV99956814; called by muse, mutect2, varscan2
- ARHGAP32 | c.1099G>C p.E367Q (on ENST00000310343 / NM_001378025.1; = p.E18Q on NM_014715.4) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV59850139; called by muse, mutect2, varscan2
- ARPC2 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55286028, COSV99826615; called by muse, mutect2, varscan2
- ASH1L | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV100853243; called by muse, mutect2
- ATAD5 | c.1569G>C p.R523S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100429781; called by muse, mutect2, varscan2
- ATF7IP2 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100202557; called by muse, mutect2, varscan2
- ATP13A4 | c.3042C>G p.I1014M | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV100710207; called by muse, mutect2, varscan2
- ATP8A2 | c.3179G>T p.G1060V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680945; called by muse, mutect2, varscan2
- BABAM2 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as COSV100567557; called by muse, mutect2, varscan2
- BBOF1 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV101223573, COSV101223775; called by muse, mutect2, varscan2
- BCLAF1 | c.1625C>G p.S542C | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100786502, COSV100786803, COSV62140805; called by muse, mutect2, varscan2
- BRF1 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1400157627, COSV100527018; called by muse, mutect2, varscan2
- C1QTNF9 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59656575; called by muse, mutect2, varscan2
- C3orf20 | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV53786973; called by muse, mutect2, varscan2
- C3orf70 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs775400044, COSV100621175; called by muse, mutect2, varscan2
- CACNG2 | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV100268651; called by muse, mutect2, varscan2
- CARS1 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99542299; called by muse, mutect2, varscan2
- CASK | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100586884, COSV100586947; called by muse, mutect2, varscan2
- CATSPER2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.283); catalogued as COSV100390639; called by muse, mutect2, varscan2
- CCDC171 | c.3702G>C p.L1234F | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101047471, COSV101048286; called by muse, mutect2, varscan2
- CCDC66 | c.1591G>C p.E531Q (on ENST00000394672 / NM_001353147.1; = p.E497Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV100413816, COSV100414172; called by muse, mutect2, varscan2
- CCDC88A | c.3054G>C p.Q1018H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV55061335; called by muse, mutect2, varscan2
- CCDC96 | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs533110978, COSV100027849; called by muse, mutect2, varscan2
- CCNT1 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56065642; called by muse, mutect2, varscan2
- CD101 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99869333; called by muse, mutect2, varscan2
- CDAN1 | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99141216, COSV99142576; called by muse, mutect2, varscan2
- CDH15 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.035); catalogued as COSV57027977; called by muse, mutect2, varscan2
- CENPJ | c.2853G>C p.Q951H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV101121478; called by muse, mutect2, varscan2
- CFAP70 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100160333; called by muse, mutect2, varscan2
- CFHR3 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.326); catalogued as COSV100807474; called by muse, mutect2, varscan2
- CLCNKA | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421131685, COSV100509946; called by muse, mutect2, varscan2
- CNKSR3 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.159); catalogued as COSV101401314; called by muse, mutect2, varscan2
- CNR1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV62986822; called by muse, mutect2
- COL11A1 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534777436, COSV62194223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs749156062, COSV52854257; called by muse, mutect2, varscan2
- COQ6 | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99473835; called by muse, mutect2, varscan2
- CORO1B | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100396336; called by muse, mutect2, varscan2
- CPA6 | c.1253G>T p.C418F | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99913053; called by muse, mutect2, varscan2
- CPO | c.420G>C p.R140S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99786415; called by muse, mutect2, varscan2
- CREBBP | c.3793G>C p.D1265H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99269167; called by muse, mutect2, varscan2
- DCAF12L2 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV63583042; called by muse, mutect2, varscan2
- DCC | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100498962; called by muse, mutect2, varscan2
- DDR2 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100906322; called by muse, mutect2, varscan2
- DHRS7B | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs536195532, COSV100683897; called by muse, mutect2, varscan2
- DMXL2 | c.6871C>G p.Q2291E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as rs1416496105, COSV99196116, COSV99196190; called by mutect2, varscan2
- DNAH11 | c.12917T>C p.L4306P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178254; called by muse, mutect2, varscan2
- DNAH7 | c.1450_1451del p.S484Cfs*5 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs756123132; called by pindel, varscan2
- DOP1B | c.4082C>G p.S1361* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV101215182; called by muse, mutect2, varscan2
- DPF2 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99361449; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2504T>G p.L835R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100348948; called by mutect2, varscan2
- ELSPBP1 | c.573G>C p.K191N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as rs1268195499, COSV100353543; called by muse, varscan2
- EPB41L2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100440424; called by muse, mutect2, varscan2
- ERGIC2 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV64112799; called by muse, mutect2, varscan2
- EXOSC8 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99524008, COSV99524016; called by muse, mutect2, varscan2
- EZR | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as rs1275105452, COSV99791713; called by muse, mutect2, varscan2
- FAM118B | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100796849; called by muse, mutect2, varscan2
- FAM160B1 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100985354; called by muse, mutect2, varscan2
- FAM71F1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.006); catalogued as COSV100170810, COSV59373509; called by muse, mutect2, varscan2
- FAM91A1 | c.1354C>G p.L452V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100593496; called by muse, varscan2
- FAT1 | c.9253dup p.L3085Pfs*2 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | catalogued as rs749145480; called by mutect2, pindel, varscan2
- FBN3 | c.7372C>T p.Q2458* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs927168879, COSV99560349; called by muse, mutect2
- FBXW9 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100790306, COSV63510602; called by muse, mutect2, varscan2
- FCN1 | c.918G>C p.W306C | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65662745; called by muse, mutect2, varscan2
- FLNA | c.7604T>C p.V2535A (on ENST00000369850 / NM_001110556.2; = p.V2527A on NM_001456.3) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs886039104, COSV100774438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOSL1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100440851; called by muse, mutect2
- GCSAM | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100453216, COSV58264551; called by muse, mutect2, varscan2
- GDA | c.387G>C p.R129S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV99428996, COSV99429507; called by muse, mutect2, varscan2
- GLB1 | c.1434G>C p.E478D | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100257109; called by muse, mutect2, varscan2
- GLMP | c.471G>C p.W157C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55293047, COSV99827805; called by muse, mutect2, varscan2
- GP2 | c.1175C>T p.S392F (on ENST00000381362 / NM_001007240.3; = p.S389F on NM_001502.4) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100221351; called by muse, mutect2, varscan2
- HASPIN | c.1879A>C p.S627R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99560673; called by muse, mutect2, varscan2
- HAUS6 | c.2416C>G p.P806A | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV100997787; called by muse, mutect2, varscan2
- HAUS6 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV100787202; called by muse, mutect2, varscan2
- HLA-DRA | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100895052; called by muse, mutect2, varscan2
- HMCN1 | c.340-1G>T p.X114_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99626252; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1049G>A p.R350K (on ENST00000354667 / NM_031243.3; = p.R338K on NM_002137.4) | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.636); catalogued as COSV61158016; called by muse, mutect2, varscan2
- HSP90B1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100236380; called by muse, mutect2, varscan2
- HSPA12A | c.1584C>G p.I528M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100979742; called by muse, mutect2
- HSPA8 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV57086384, COSV99914288; called by muse, mutect2, varscan2
- HTN1 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs1211415235, COSV99887468; called by muse, mutect2, varscan2
- IFI16 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1359441491, COSV99857252; called by muse, mutect2, varscan2
- IFT140 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV101276311; called by muse, mutect2, varscan2
- INPP4B | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); catalogued as rs778253517, COSV99523605; called by muse, varscan2
- IRF2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66929478, COSV66929583; called by muse, varscan2
- IRGC | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV99746157; called by muse, mutect2, varscan2
- JAG1 | c.2334C>G p.I778M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV99652609; called by muse, mutect2, varscan2
- KANK2 | c.2524G>A p.E842K (on ENST00000586659 / NM_001379562.1; = p.E850K on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.735); catalogued as rs1406586712, COSV100763088; called by muse, mutect2
- KCTD10 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1337942597, COSV99949140; called by muse, mutect2, varscan2
- KDM3B | c.1582C>A p.Q528K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100069334, COSV58693438; called by muse, mutect2, varscan2
- KDM6B | c.2591C>G p.S864C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV54681475, COSV99640984; called by muse, mutect2
- KIAA0513 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99260644; called by muse, mutect2, varscan2
- KIAA1217 | c.4288G>A p.D1430N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV100286356; called by muse, mutect2, varscan2
- KIAA1841 | c.1983G>C p.M661I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54379853; called by muse, mutect2, varscan2
- KIF19 | c.2554G>C p.E852Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV63429296, COSV99057434; called by muse, mutect2
- KIF6 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758037; called by muse, mutect2, varscan2
- KLHL7 | c.716C>G p.S239* (on ENST00000339077 / NM_001031710.3; = p.S191* on NM_018846.5) | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | catalogued as COSV100177878; called by muse, mutect2, varscan2
- KLRC3 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101122900; called by muse, varscan2
- KRT75 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777276211, COSV99359283, COSV99359556; called by muse, mutect2, varscan2
- LAMB1 | c.2900C>A p.S967* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as rs1454089102, COSV99740264; called by muse, varscan2
- LARP4 | c.536-1G>T p.X179_splice | Splice Site (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99529133; called by muse, mutect2, varscan2
- LARS1 | c.3136G>C p.D1046H (on ENST00000394434 / NM_020117.11; = p.D1019H on NM_016460.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99198522; called by muse, mutect2, varscan2
- LMNB1 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV99745733; called by muse, mutect2, varscan2
- LMTK2 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99806367; called by muse, mutect2, varscan2
- LRRC40 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1481021129, COSV100918731; called by muse, mutect2, varscan2
- LUM | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.171); catalogued as COSV99898925; called by muse, mutect2, varscan2
- MACF1 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100483420; called by muse, mutect2
- MACROH2A1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV100427577; called by muse, mutect2, varscan2
- MAGI2 | c.2042G>C p.R681P | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100833776, COSV62660499; called by muse, mutect2
- MAN1B1 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 85/132 reads (64%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs777414894, COSV100814423; called by muse, mutect2, varscan2
- MARF1 | c.4960G>C p.E1654Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100705713; called by muse, mutect2, varscan2
- MFAP1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99979743; called by muse, mutect2, varscan2
- MFSD6L | c.906C>G p.I302M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100266293; called by muse, mutect2, varscan2
- MME | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201935217, COSV64712085; called by muse, mutect2
- MTMR1 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100953076; called by muse, mutect2, varscan2
- MTMR3 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100070590; called by muse, mutect2, varscan2
- MUC16 | c.28028C>G p.S9343* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV101198978, COSV67445063; called by muse, mutect2, varscan2
- MX1 | c.1587G>C p.Q529H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as COSV99912515; called by muse, mutect2, varscan2
- MYO5C | c.2897C>G p.S966* | Nonsense Mutation (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99954363; called by muse, mutect2, varscan2
- MYOF | c.6054C>G p.F2018L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV100825458; called by muse, mutect2, varscan2
- MYOF | c.5473G>T p.E1825* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100825461; called by muse, varscan2
- MYOM1 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV99865899; called by muse, mutect2, varscan2
- N4BP2L2 | c.2725G>C p.E909Q (on ENST00000674422; = p.E480Q on NM_033111.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV100678841; called by muse, mutect2, varscan2
- NAV3 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99888537; called by muse, mutect2, varscan2
- NDN | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs1264404808, COSV100086337; called by muse, mutect2, varscan2
- NEDD4 | c.3199C>G p.H1067D (on ENST00000508342 / NM_001284338.1; = p.H648D on NM_006154.4) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100163495, COSV59065540; called by muse, mutect2, varscan2
- NLRC3 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100072589; called by muse, mutect2, varscan2
- NLRC4 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV61592469, COSV61592671, COSV61594910; called by muse, mutect2
- NLRP1 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99333422; called by muse, mutect2
- NSD2 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100372995; called by muse, mutect2, varscan2
- OLFML2A | c.1257G>A p.M419I | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99992445; called by muse, mutect2, varscan2
- OR14I1 | c.201G>T p.L67F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100700450; called by muse, mutect2, varscan2
- OR1A1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100410737, COSV58404896; called by muse, mutect2, varscan2
- OR2A2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763818273, COSV68872280, COSV68872394; called by muse, mutect2, varscan2
- OR2M4 | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | catalogued as COSV100141068; called by muse, mutect2
- OR2M5 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs754285740, COSV100822778; called by muse, mutect2, varscan2
- OR2W1 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV65851706, COSV65851893; called by muse, mutect2, varscan2
- OR5AP2 | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99075727, COSV99075728; called by muse, mutect2, varscan2
- OR9I1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1237605951, COSV100109626; called by muse, mutect2, varscan2
- PACSIN2 | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99606032; called by muse, mutect2, varscan2
- PADI1 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100969030, COSV64938748; called by muse, mutect2, varscan2
- PAX3 | c.815C>A p.A272E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100399315, COSV100400023; called by muse, mutect2, varscan2
- PCDHB5 | c.2062T>C p.Y688H | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as COSV99167758; called by muse, mutect2, varscan2
- PCDHGC3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV99338921; called by muse, mutect2, varscan2
- PIGS | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV99256752; called by muse, mutect2, varscan2
- PIPOX | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100037889; called by muse, mutect2, varscan2
- PMS1 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100575532; called by muse, mutect2, varscan2
- PNMA3 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs782057915, COSV64722119; called by muse, varscan2
- POM121 | c.1475C>G p.S492W (on ENST00000434423; = p.S227W on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); catalogued as COSV99987890; called by muse, mutect2, varscan2
- PPIB | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs750682454, COSV100254464; called by muse, mutect2, varscan2
- PPP2R3A | c.3253G>C p.D1085H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99386710; called by muse, mutect2
- PPP2R5A | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV99806514; called by muse, mutect2, varscan2
- PREPL | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV53216602, COSV53219756; called by muse, mutect2, varscan2
- PRKCI | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99855715; called by muse, mutect2, varscan2
- PRRT3 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569295912, COSV55978370; called by muse, mutect2, varscan2
- PRSS21 | c.840G>A p.W280* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99135486; called by muse, mutect2, varscan2
- PRX | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.346); catalogued as COSV52533573, COSV99397591; called by muse, mutect2, varscan2
- PRX | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99397592; called by muse, mutect2, varscan2
- PRX | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs1055634958, COSV52529105; called by muse, mutect2, varscan2
- PSMC5 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV99856305; called by muse, mutect2, varscan2
- RAB39B | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV101034944; called by muse, varscan2
- RAB39B | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101034945; called by muse, varscan2
- RAB6A | c.284T>A p.I95N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100154911; called by muse, mutect2, varscan2
- RAC1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV61823874; called by muse, mutect2, varscan2
- RAD21 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1337089126, COSV52065700, COSV99814949; called by muse, mutect2, varscan2
- RAI1 | c.2847G>A p.M949I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV99883665; called by muse, mutect2, varscan2
- RARB | c.203C>A p.S68Y (on ENST00000383772 / NM_001290216.2; = p.S61Y on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100412231; called by muse, mutect2, varscan2
- RBBP8 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.958); catalogued as COSV100507189, COSV59094471; called by muse, mutect2, varscan2
- RPS18 | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV101005590, COSV65851635; called by muse, mutect2, varscan2
- RUNDC3B | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100406885; called by muse, mutect2, varscan2
- RXFP1 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.028); catalogued as COSV100313626; called by muse, mutect2, varscan2
- SAMD9 | c.2049C>G p.F683L | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV101180161, COSV101180180; called by muse, mutect2, varscan2
- SDCCAG8 | c.1922G>C p.R641T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100654019, COSV59405078; called by muse, mutect2, varscan2
- SDR9C7 | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53290401, COSV99524559; called by muse, mutect2, varscan2
- SERPINA12 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100369617; called by muse, mutect2, varscan2
- SI | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV52298753; called by muse, mutect2, varscan2
- SLC25A48 | c.163-1G>T p.X55_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99191961; called by muse, mutect2, varscan2
- SMARCAL1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100619830; called by muse, mutect2
- SOGA1 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99413232; called by muse, mutect2, varscan2
- SRGAP1 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.097); catalogued as COSV100754448; called by muse, mutect2, varscan2
- SRSF5 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV67936411; called by muse, mutect2, varscan2
- STAG2 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54358349, COSV99492729; called by muse, mutect2, varscan2
- STIL | c.3382C>A p.L1128I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99680746; called by muse, mutect2, varscan2
- STK39 | c.412A>T p.M138L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV100596385, COSV63594005; called by muse, varscan2
- SYCP2 | c.1031A>T p.E344V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100698101; called by muse, mutect2, varscan2
- SYCP2 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs1255926611, COSV100698102; called by muse, mutect2, varscan2
- SYTL2 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100313855; called by muse, mutect2
- TAF6L | c.1113G>C p.K371N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99585038; called by muse, mutect2, varscan2
- TAOK3 | c.2416A>G p.M806V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV101183481; called by muse, mutect2, varscan2
- TBC1D15 | c.1320G>C p.L440F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100041536; called by muse, mutect2, varscan2
- TBRG4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.141); catalogued as rs776163137, COSV99345312; called by muse, mutect2, varscan2
- TCAIM | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV100703222, COSV61240992; called by muse, mutect2, varscan2
- TCTE1 | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs988359016, COSV101025359; called by muse, mutect2, varscan2
- TG | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1455309684, COSV99599810; called by muse, mutect2, varscan2
- TGFBR1 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as rs200595614, COSV66625422; called by muse, mutect2, varscan2
- TINAG | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99449006; called by muse, mutect2, varscan2
- TLR4 | c.1103C>A p.S368* (on ENST00000355622 / NM_138554.5; = p.S328* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 44/91 reads (48%) | catalogued as COSV62922441; called by muse, mutect2, varscan2
- TMEM94 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100050223; called by muse, mutect2, varscan2
- TNFRSF10A | c.1311G>C p.E437D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as rs751666555, COSV99646111; called by muse, mutect2, varscan2
- TNIP1 | c.1828C>A p.Q610K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.359); catalogued as COSV100161214, COSV59303820; called by muse, mutect2
- TNIP1 | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100161219; called by muse, mutect2, varscan2
- TNPO1 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100473194; called by muse, mutect2, varscan2
- TNRC6B | c.4087C>G p.Q1363E (on ENST00000454349 / NM_001162501.2; = p.Q1253E on NM_015088.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100109307; called by muse, mutect2, varscan2
- TNXB | c.6812G>C p.G2271A (on ENST00000647633; = p.G2024A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.97); catalogued as COSV64476229; called by muse, mutect2, varscan2
- TOP1 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1293462818, COSV100793731; called by muse, mutect2, varscan2
- TPH1 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100000739; called by muse, mutect2, varscan2
- TRIM31 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as COSV100946765; called by muse, mutect2, varscan2
- TRIM60 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100593916, COSV100593956; called by muse, mutect2, varscan2
- TRIP12 | c.3943G>T p.E1315* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as COSV99389710; called by muse, mutect2, varscan2
- TRIP12 | c.3587C>G p.S1196C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99389711; called by muse, mutect2, varscan2
- TRIP12 | c.3452C>G p.S1151* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99389715; called by muse, mutect2, varscan2
- TRMT5 | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1380208362, COSV99711999; called by muse, mutect2, varscan2
- TRPC7 | c.1271A>C p.Y424S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100725590; called by muse, mutect2, varscan2
- TRPC7 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.768); catalogued as COSV61457421; called by muse, mutect2, varscan2
- TTC3 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.904); catalogued as COSV100695227; called by muse, mutect2, varscan2
- TTC37 | c.1202C>A p.S401* | Nonsense Mutation (SNP) | VAF 60/224 reads (27%) | catalogued as COSV62455063; called by muse, mutect2, varscan2
- TTN | c.26083C>A p.P8695T (on ENST00000591111; = p.P7768T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | PolyPhen benign (0.001); catalogued as COSV100601592, COSV59875747; called by muse, mutect2, varscan2
- TUT4 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.307); catalogued as COSV99932001; called by muse, mutect2, varscan2
- UGT1A1 | c.722_723del p.E241Gfs*16 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs797046091; called by pindel, varscan2
- UPF2 | c.2958G>C p.K986N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); catalogued as COSV100706961, COSV100707105; called by muse, mutect2, varscan2
- UQCRFS1 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV100508047; called by muse, mutect2, varscan2
- USP34 | c.9190G>T p.D3064Y | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101276827; called by muse, mutect2
- VEZT | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99703606; called by muse, mutect2, varscan2
- VWA3B | c.1326G>C p.K442N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101345975; called by muse, mutect2, varscan2
- VWA8 | c.4199C>G p.S1400* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV101022462; called by muse, mutect2, varscan2
- WDR64 | c.1472A>G p.Y491C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100843705; called by muse, mutect2, varscan2
- WDR91 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100615591, COSV100615622; called by muse, mutect2, varscan2
- WNK2 | c.2686G>T p.A896S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV99941504; called by muse, mutect2, varscan2
- ZBTB2 | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.963); catalogued as COSV100287550; called by muse, mutect2, varscan2
- ZBTB7B | c.1164G>C p.K388N (on ENST00000292176; = p.K422N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52692111, COSV52692260; called by muse, mutect2, varscan2
- ZMYM2 | c.1162G>C p.V388L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV101243600; called by muse, mutect2, varscan2
- ZNF12 | c.1676C>T p.S559F (on ENST00000405858 / NM_016265.4; = p.S521F on NM_006956.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.926); catalogued as COSV100703623; called by muse, mutect2, varscan2
- ZNF556 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.096); catalogued as COSV56913008; called by muse, varscan2
- ZNF556 | c.1097G>C p.R366T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100298642; called by muse, mutect2, varscan2
- ZNF594 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs1434713603, COSV101280424; called by muse, mutect2
- ZNF596 | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100261572; called by muse, mutect2, varscan2
- ZNF624 | c.2451C>G p.F817L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100257132; called by muse, mutect2, varscan2
- ZNF644 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs773736700, COSV100494344, COSV61349002; called by muse, mutect2, varscan2
- ZNF644 | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV100494345; called by muse, mutect2, varscan2
- CBWD5 | c.1166A>G p.K389R (on ENST00000382405 / NM_001330668.1; = p.K341R on NM_001024916.3) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.113); called by mutect2, varscan2
- EPHA2 | c.2076dup p.E693* | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | called by mutect2, pindel, varscan2
- FAT1 | c.9905dup p.Y3302* | Nonsense Mutation (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- MEIS2 | c.897_900del p.T300Ifs*12 (on ENST00000561208 / NM_170675.5; = p.T287Ifs*12 on NM_002399.3) | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- NEDD4 | c.3225del p.F1075Lfs*8 (on ENST00000508342 / NM_001284338.1; = p.F656Lfs*8 on NM_006154.4) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- PNMT | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.152); called by mutect2, varscan2
- SLA2 | c.615_616dup p.L206Pfs*4 | Frame Shift Ins (INS) | VAF 18/112 reads (16%) | called by mutect2, pindel, varscan2
- ZNF140 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2
- ABCA10 | c.3237C>T p.F1079= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99288188; called by muse, mutect2, varscan2
- ABCA13 | c.6771G>T p.L2257= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1352661666, COSV101329975; called by muse, mutect2
- ACADM | c.756C>T p.F252= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs749692458, COSV57714198; called by muse, mutect2, varscan2
- ACLY | c.2010C>T p.L670= | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as COSV100709586; called by muse, mutect2, varscan2
- ACOX1 | c.798G>T p.V266= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99503395; called by muse, mutect2, varscan2
- ADRA1A | c.333C>T p.T111= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1305250932, COSV52367222; called by mutect2, varscan2
- AKAP3 | c.1734T>A p.I578= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV57419203, COSV99961924; called by muse, mutect2, varscan2
- ARL4A | c.321G>A p.R107= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1313712797, COSV100775896; called by muse, mutect2, varscan2
- ARPP21 | c.2337G>C p.L779= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99491445; called by muse, mutect2
- BRD4 | c.1794G>A p.T598= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs201603972, COSV99650162; called by muse, mutect2, varscan2
- C18orf25 | c.885G>C p.L295= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99959886; called by muse, mutect2, varscan2
- CCNF | c.1686C>T p.L562= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1246476451, COSV53539890, COSV53542771; called by muse, mutect2, varscan2
- CHRNB1 | c.480C>T p.F160= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1416889935, COSV99548196; called by muse, mutect2, varscan2
- CHST1 | c.78C>T p.F26= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100346112; called by muse, mutect2, varscan2
- CLP1 | c.225G>C p.L75= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100239773; called by muse, mutect2, varscan2
- CWC22 | c.1587C>T p.F529= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1443620083, COSV55428598, COSV99843939; called by muse, mutect2, varscan2
- DCANP1 | c.36G>A p.S12= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs142525704; called by muse, mutect2, varscan2
- EFCAB6 | c.771G>A p.E257= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV53060183, COSV99412849; called by muse, mutect2, varscan2
- FASTK | c.1587C>G p.L529= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99879630; called by muse, mutect2
- FGF13 | c.699G>T p.L233= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as COSV100263861, COSV100264526, COSV59543589; called by muse, mutect2, varscan2
- FRMPD2 | c.318C>G p.V106= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100563663; called by muse, mutect2, varscan2
- GABRR3 | c.213T>C p.D71= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV101512271; called by muse, mutect2
- GRIA2 | c.1359C>T p.I453= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs752578545, COSV52383835; called by muse, mutect2, varscan2
- HERC2 | c.14055C>G p.L4685= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99871974; called by muse, mutect2, varscan2
- INSC | c.693G>A p.L231= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ITGA2 | c.516C>G p.L172= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as COSV99670499; called by muse, mutect2, varscan2
- KCNS2 | c.498C>T p.L166= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1166286283, COSV99750933; called by muse, mutect2, varscan2
- LAMB1 | c.2994C>G p.L998= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99740260; called by muse, varscan2
- LRFN5 | c.1788C>T p.H596= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs770209727, COSV53245814, COSV53262134; called by muse, mutect2, varscan2
- MYCBP2 | c.13461G>C p.V4487= (on ENST00000357337; = p.V4525= on NM_015057.5) | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100629643; called by muse, mutect2, varscan2
- MYO1H | c.1899G>T p.V633= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV100183303; called by muse, mutect2, varscan2
- NHLRC1 | c.762T>C p.T254= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100513427; called by muse, mutect2, varscan2
- NIN | c.4473G>T p.L1491= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99812535; called by muse, mutect2, varscan2
- NKX2-4 | c.756G>A p.A252= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1362692948, COSV100698582; called by muse, mutect2, varscan2
- OR4D6 | c.12C>A p.I4= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs1224349944, COSV100271624; called by muse, mutect2, varscan2
- OR9Q2 | c.36C>T p.F12= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV61111412; called by muse, mutect2, varscan2
- PAK6 | c.21G>A p.K7= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53047231; called by muse, mutect2, varscan2
- PCDHA5 | c.2052C>T p.G684= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1554129619, COSV65356030; called by muse, mutect2, varscan2
- PCDHGA2 | c.1803C>T p.N601= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV54043364; called by muse, mutect2, varscan2
- PER2 | c.3588G>A p.T1196= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs548759609, COSV99611632; called by muse, mutect2, varscan2
- PPP3CC | c.156G>A p.L52= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs747232518, COSV99251923; called by mutect2, varscan2
- PRKX | c.426G>T p.G142= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99467839; called by muse, mutect2, varscan2
- RC3H1 | c.507C>T p.L169= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1045655358, COSV99281170; called by muse, mutect2, varscan2
- REC8 | c.138C>G p.L46= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100268925; called by muse, mutect2, varscan2
- RNF175 | c.678C>T p.I226= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99923977; called by muse, mutect2, varscan2
- RPS20 | c.66C>T p.I22= | Silent (SNP) | VAF 75/159 reads (47%) | catalogued as COSV99154799; called by muse, mutect2, varscan2
- SERINC5 | c.1185C>T p.F395= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs368333548; called by muse, mutect2, varscan2
- ST3GAL6 | c.972C>T p.L324= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs557024529, COSV99504651; called by muse, mutect2, varscan2
- STON1 | c.1014C>T p.F338= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100561645; called by muse, mutect2, varscan2
- TBCD | c.2646G>C p.L882= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100832860; called by muse, mutect2, varscan2
- TBL2 | c.861C>T p.F287= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs1452442971, COSV99979539; called by muse, varscan2
- TCF25 | c.1839C>T p.F613= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs759109053, COSV99642574; called by muse, mutect2, varscan2
- TCF7L2 | c.1386G>A p.K462= (on ENST00000355995 / NM_001367943.1; = p.K439= on NM_030756.5) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs12359833, COSV99525451; called by muse, varscan2
- TESPA1 | c.990C>G p.L330= (on ENST00000316577 / NM_001098815.3; = p.L192= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100345018; called by muse, mutect2, varscan2
- TMC4 | c.1884C>T p.I628= (on ENST00000617472 / NM_001145303.3; = p.I622= on NM_144686.4) | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV55828103; called by muse, mutect2
- TMED6 | c.651C>T p.I217= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV54743067; called by muse, mutect2, varscan2
- TMEM174 | c.366C>T p.F122= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99703747; called by muse, mutect2, varscan2
- TNPO2 | c.267C>T p.I89= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100790307; called by muse, mutect2, varscan2
- TNS3 | c.1869C>T p.V623= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100235213; called by muse, mutect2, varscan2
- TSC2 | c.3645G>A p.P1215= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs758114962, COSV54756843; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.29493G>T p.S9831= (on ENST00000591111; = p.S8904= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100601589; called by muse, varscan2
- TWF1 | c.228G>A p.Q76= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100285985; called by muse, mutect2, varscan2
- TWNK | c.1521C>G p.V507= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV99272138; called by muse, mutect2, varscan2
- UBR5 | c.6246G>A p.G2082= | Silent (SNP) | VAF 73/185 reads (39%) | catalogued as COSV99640099; called by muse, mutect2, varscan2
- USP21 | c.927C>G p.L309= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99237258; called by muse, mutect2, varscan2
- ZIC3 | c.816C>T p.F272= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs760583163, COSV99798613; called by muse, mutect2, varscan2
- ZNF521 | c.3768C>T p.F1256= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100831685, COSV64128904; called by muse, mutect2, varscan2
- ZNF556 | c.879G>A p.G293= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV56911407; called by muse, mutect2, varscan2
- ZNF804A | c.2202G>A p.Q734= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100167037, COSV100169824; called by muse, mutect2, varscan2
- ZSCAN26 | c.720C>T p.F240= (on ENST00000623276 / NM_001111039.2; = p.F106= on NM_152736.5) | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-34821G>C | Intron (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99399146; called by muse, mutect2, varscan2
- GPM6B | chrX:13772977 G>T | 3'Flank (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100366104; called by muse, mutect2, varscan2
- MIR541 | n.47G>A | RNA (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- NDUFA3 | c.*89del | 3'UTR (DEL) | VAF 4/24 reads (17%) | catalogued as rs768691187; called by pindel, varscan2
- NRG1 | c.502+31292C>G | Intron (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99828059; called by muse, mutect2, varscan2
- SNORD116-6 | n.90G>A | RNA (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- SSPOP | n.1696G>A | RNA (SNP) | VAF 5/25 reads (20%) | catalogued as rs770473754, COSV100022275, COSV100022581; called by muse, mutect2, varscan2
- UBXN4 | c.-1G>T | 5'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as rs1290454309, COSV99738568, COSV99738834; called by muse, mutect2, varscan2
- Y_RNA | chr7:75514678 C>T | 5'Flank (SNP) | VAF 10/45 reads (22%) | called by mutect2, varscan2
- Y_RNA | chr7:75515790 C>G | 5'Flank (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75516175 C>T | 5'Flank (SNP) | VAF 20/86 reads (23%) | catalogued as rs1554485796; called by muse, mutect2, varscan2
- ZNF99 | c.*69A>C | 3'UTR (SNP) | VAF 21/64 reads (33%) | catalogued as COSV101233762; called by muse, mutect2, varscan2
